Somatic mutation profile of tumor specimen TCGA-AA-3952-01A (aliquot TCGA-AA-3952-01A-01W-0995-10) from TCGA case TCGA-AA-3952, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.1 years (24,868 days).
Specimen TCGA-AA-3952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 870eb5fb-ec73-4480-8787-1f7c5bcfd761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3952-10A (Blood Derived Normal), aliquot TCGA-AA-3952-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18f35388-8e8d-4fdb-ac33-f2160dd304ab

The open-access MAF lists 102 somatic variants for this specimen: 74 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 55, Silent 28, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 3, In Frame Del 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3920_3924del p.I1307Rfs*6 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs1064794229; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as rs748819386, CM1413479, COSV100068148; called by muse, mutect2, varscan2
- ACAN | c.5561A>C p.E1854A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV100716718; called by muse, mutect2
- ACSS1 | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100053488; called by muse, mutect2
- ASCC3 | c.3590G>A p.R1197Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1375395896, COSV100225375; called by muse, mutect2
- ATF7IP2 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs746602868, COSV61095541; called by muse, mutect2, varscan2
- BTBD11 | c.2513G>A p.R838H (on ENST00000280758 / NM_001018072.2; = p.R375H on NM_001017523.2) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs777803244, COSV55038671; called by muse, mutect2, varscan2
- CACNA1E | c.5078G>A p.R1693H | Missense Mutation (SNP) | VAF 192/492 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs964315512, COSV62404935; called by muse, mutect2, varscan2
- CD2BP2 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99976990; called by muse, mutect2, varscan2
- CNTRL | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as rs140149582; called by muse, mutect2, varscan2
- CREB3L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1395366298, COSV57800550; called by muse, mutect2, varscan2
- CRNN | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV55124060; called by muse, mutect2, varscan2
- CYP2C8 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100987946, COSV64879125; called by muse, mutect2, varscan2
- DDX58 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 66/174 reads (38%) | catalogued as rs371404578; called by muse, mutect2, varscan2
- DUT | c.695_697del p.E232del (on ENST00000331200 / NM_001025248.2; = p.E144del on NM_001948.4) | In Frame Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs774179371; called by pindel, varscan2
- EPHB4 | c.2456G>A p.R819K | Missense Mutation (SNP) | VAF 153/402 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100639430; called by muse, varscan2
- F8 | c.4738C>G p.L1580V | Missense Mutation (SNP) | VAF 381/470 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV64279158; called by muse, mutect2, varscan2
- FLG | c.8344G>A p.G2782S | Missense Mutation (SNP) | VAF 81/453 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs748391293, COSV64246443; called by muse, mutect2, varscan2
- GFPT2 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.35); catalogued as rs774417416, COSV53806218; called by muse, mutect2
- GRHL2 | c.1077G>A p.W359* | Nonsense Mutation (SNP) | VAF 172/547 reads (31%) | catalogued as COSV52555432; called by muse, mutect2, varscan2
- GRM6 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99179484; called by muse, mutect2, varscan2
- HERC1 | c.1752G>T p.W584C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101496405; called by mutect2, varscan2
- ITGA7 | c.2267A>T p.Q756L (on ENST00000555728; = p.Q712L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs771597583, COSV57701766; called by muse, mutect2, varscan2
- KHDC3L | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100950373; called by muse, mutect2, varscan2
- L1TD1 | c.2049_2050del p.Q683Hfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs1222162331; called by mutect2, pindel
- MAP2K4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62254869; called by muse, mutect2, varscan2
- MCF2L2 | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777104963, COSV100191668; called by muse, mutect2, varscan2
- MINDY3 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs140756231; called by muse, mutect2, varscan2
- NAV1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99818436; called by muse, mutect2, varscan2
- NFU1 | c.289T>G p.S97A (on ENST00000410022 / NM_001002755.4; = p.S73A on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58007795; called by muse, mutect2, varscan2
- NTN4 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771714554; called by muse, mutect2, varscan2
- PCDH11X | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV53508091; called by muse, mutect2, varscan2
- PDE6A | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV99677820; called by muse, mutect2
- PDGFRA | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs201503614, COSV57266111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POSTN | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 303/803 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753830117, COSV65714455; called by muse, varscan2
- RAD54B | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 63/183 reads (34%) | catalogued as COSV60251169, COSV60251318; called by muse, mutect2, varscan2
- RANBP2 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99311488; called by muse, mutect2, varscan2
- RIPK4 | c.1207C>T p.R403C (on ENST00000352483; = p.R355C on NM_020639.3) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs760710644, COSV60191555; called by muse, mutect2, varscan2
- RUNX1T1 | c.1348+1G>A p.X450_splice (on ENST00000265814 / NM_001198628.1; = p.X423_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 58/134 reads (43%) | catalogued as COSV56164354; called by muse, mutect2, varscan2
- RYR3 | c.10879G>T p.E3627* (on ENST00000389232; = p.E3628* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV101212166; called by muse, mutect2, varscan2
- SEL1L2 | c.1998C>A p.H666Q | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV53157714, COSV99532809; called by muse, mutect2, varscan2
- SEMA5B | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV99531079; called by muse, mutect2, varscan2
- SESTD1 | c.1954C>G p.P652A | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100090277; called by muse, mutect2, varscan2
- SIX6 | c.422A>C p.H141P | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV59801685, COSV59801773; called by mutect2, varscan2
- SLC41A3 | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV59990805; called by muse, mutect2, varscan2
- SLITRK1 | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.781); catalogued as rs939739336, COSV100999836; called by muse, mutect2, varscan2
- SMG6 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 195/339 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs371760718; called by muse, mutect2, varscan2
- SUOX | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs535313141, COSV99906960; called by muse, mutect2, varscan2
- TBC1D2 | c.2383G>A p.V795M | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59782306, COSV59782613; called by muse, mutect2, varscan2
- THBS1 | c.3268-2A>T p.X1090_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99527663; called by mutect2, varscan2
- TMEM94 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100049971; called by muse, varscan2
- TOGARAM1 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100817882; called by muse, varscan2
- UGT2A1 | c.1442T>G p.L481R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54146899; called by muse, mutect2, varscan2
- USH2A | c.8741G>A p.R2914Q | Missense Mutation (SNP) | VAF 170/428 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs760779633, COSV100230875, COSV56339365; called by muse, mutect2, varscan2
- ZNF106 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 186/480 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772280487, COSV99782304; called by muse, mutect2, varscan2
- ZNF343 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.692); catalogued as rs1289411596, COSV99601272; called by muse, mutect2
- ZNF385B | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 161/570 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200150920, COSV61176803; called by muse, mutect2, varscan2
- ZNF831 | c.4355C>T p.A1452V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100925860; called by muse, mutect2, varscan2
- AMPD2 | c.1352T>G p.I451S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGEF38 | c.623dup p.E209Gfs*71 (on ENST00000420470 / NM_001242729.2; = p.E209Gfs*35 on NM_017700.1) | Frame Shift Ins (INS) | VAF 30/60 reads (50%) | called by mutect2, pindel, varscan2
- C21orf58 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- CD244 | c.763_764del p.R255Efs*84 (on ENST00000368033 / NM_001166663.2; = p.R250Efs*84 on NM_016382.4) | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by pindel, varscan2
- DNAH7 | c.992_994del p.W331del | In Frame Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- EPHB4 | c.2465_2469del p.W822Yfs*11 | Frame Shift Del (DEL) | VAF 104/360 reads (29%) | called by pindel, varscan2
- GDPD3 | c.744_747dup p.L250Vfs*32 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- MBLAC2 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, varscan2
- NUP133 | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- PTPN23 | c.364+5_364+13del p.X122_splice | Splice Site (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- PTPRH | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RABGEF1 | c.484T>C p.F162L (on ENST00000439720 / NM_001287061.2; = p.F149L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SHC4 | c.1884del p.N629Tfs*11 | Frame Shift Del (DEL) | VAF 214/760 reads (28%) | called by mutect2, pindel, varscan2
- TOX4 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WNT9B | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACSBG1 | c.504G>A p.P168= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs779049682, COSV51908946; called by muse, mutect2, varscan2
- ATXN2L | c.1054C>T p.L352= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV57379682; called by muse, mutect2, varscan2
- AXDND1 | c.2421T>C p.S807= | Silent (SNP) | VAF 110/271 reads (41%) | catalogued as COSV100858278; called by muse, mutect2, varscan2
- CDC23 | c.351G>C p.L117= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV101202982, COSV67508648; called by muse, mutect2, varscan2
- CP | c.57G>A p.A19= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs775969249, COSV52829053; called by muse, mutect2, varscan2
- DSCAM | c.5859C>T p.S1953= | Silent (SNP) | VAF 86/227 reads (38%) | catalogued as rs756653902, COSV68037178; called by muse, mutect2, varscan2
- EPHA2 | c.141G>A p.P47= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs370213656; called by muse, mutect2, varscan2
- FOXJ3 | c.1689G>A p.V563= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV62365557; called by muse, mutect2, varscan2
- GLUD1 | c.192C>T p.P64= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV53281532; called by muse, mutect2, varscan2
- HIVEP1 | c.6249G>A p.R2083= | Silent (SNP) | VAF 72/204 reads (35%) | catalogued as COSV101044866; called by muse, mutect2, varscan2
- HMGCS1 | c.1086T>C p.P362= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV100284922; called by muse, mutect2
- IFFO1 | c.579C>T p.P193= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs530504239, COSV59109823; called by muse, mutect2, varscan2
- KRT3 | c.1488C>T p.D496= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs372122010; called by muse, mutect2, varscan2
- MGAM | c.3255G>C p.V1085= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs200667889, COSV72075966; called by muse, mutect2, varscan2
- MYO6 | c.1776G>A p.Q592= | Silent (SNP) | VAF 76/123 reads (62%) | catalogued as COSV64121623; called by muse, mutect2, varscan2
- MYORG | c.1116C>T p.N372= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs773122688, COSV52628224; called by muse, mutect2, varscan2
- NUP62CL | c.291C>T p.L97= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PCDHGC5 | c.921C>T p.P307= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, varscan2
- PPP1R35 | c.666C>T p.T222= | Silent (SNP) | VAF 323/344 reads (94%) | catalogued as rs569808693, COSV99439842; called by muse, mutect2, varscan2
- TFAP2A | c.501G>C p.P167= (on ENST00000482890; = p.P159= on NM_001032280.3) | Silent (SNP) | VAF 71/217 reads (33%) | catalogued as COSV60237933; called by muse, mutect2, varscan2
- THEG | c.132C>T p.D44= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV61075052; called by muse, mutect2, varscan2
- TMC5 | c.144C>T p.P48= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as rs267604430, COSV101196611, COSV66864847; called by muse, mutect2, varscan2
- UGT1A6 | c.1374G>A p.V458= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100529849; called by muse, mutect2
- UGT3A1 | c.1425C>T p.A475= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV57103902; called by muse, mutect2, varscan2
- VPS26B | c.291A>G p.G97= | Silent (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ZC3HAV1 | c.2139C>T p.T713= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV54301575; called by muse, mutect2, varscan2
- ZNF214 | c.561G>A p.Q187= | Silent (SNP) | VAF 57/93 reads (61%) | catalogued as COSV53483866; called by muse, mutect2, varscan2
- ZNF862 | c.3426G>A p.A1142= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs139787517; called by muse, mutect2, varscan2
